Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0J8, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0J8-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis & History:

female with invasive ductal carcinoma right breast.

Specimens Submitted:

- 1: SP: Sentinel node #1 level one right axilla (fs)
- 2: SP: Sentinel node #2 level one right axilla (fs)
- 3: SP: Right breast tissue
- 4: SP: Medial margin, right breast
- 5: SP: Superior margin, right breast
- 6: SP: Inferior margin, right breast
- 7: SP: Lateral margin, right breast
- 8: SP: Posterior margin, right breast

DIAGNOSIS:

Summary of findings in this case:

Invasive lobular carcinoma spans 2.2 cm and does not involve the separately submitted margins.

Sentinel lymph nodes: 1/2.

Non-sentinel lymph nodes: 0

Total lymph nodes: 1/2.

Type of metastasis: ITC

1. LYMPH NODE SENTINEL #1, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H/E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3) SHOW NO EVIDENCE OF METASTATIC TUMOR.
2. LYMPH NODE, SENTINEL #2 LEVEL I RIGHT AXILLA; EXCISION:
- RARE CYTOKERATIN-POSITIVE CELLS (ABOUT 10 CELLS) ARE PRESENT IN 1 OF 1 LYMPH NODE(S). THESE CELLS ARE NOT IDENTIFIED ON THE CORRESPONDING H/E STAINED SECTIONS OR IN THE FROZEN SECTION SLIDE OR IN THE FROZEN SECTION CONTROL SLIDE.
3. BREAST, RIGHT; EXCISION:
- INVASIVE LOBULAR CARCINOMA, CLASSICAL TYPE, MEASURING 2.2 CM IN LARGEST DIMENSION MICROSCOPICALLY. A NEGATIVE E-CADHERIN STAINING SUPPORTS THE MORPHOLOGIC IMPRESSION OF LOBULAR PHENOTYPE.
- EXTENSIVE LOBULAR CARCINOMA IN SITU (LCIS) IS ALSO IDENTIFIED.
- NO CALCIFICATIONS ARE IDENTIFIED IN EITHER THE INVASIVE OR IN SITU

** Continued on next page **

ICD-0-3

carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9 lw 10/22/11

[page 2 of 6]
----- Page 2 of 6
COMPONENT.

- NO VASCULAR INVASION IS NOTED.
- SURGICAL MARGINS (SEE PARTS 4-8).
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES.
- RESULTS OF STAINS (HER2-NEU) ARE AS FOLLOWS:

HER2

Negative (1+)

(1% of invasive tumor cells exhibit complete membranous staining;

Uniformity of staining: absent;

Homogeneous, dark circumferential pattern: absent)

Comment: Controls are satisfactory.

PATHWAY anti-HER-2/neu is an FDA-approved rabbit monoclonal primary antibody (clone 4B5) directed against the internal domain of the c-erbB-2 oncoprotein (HER2) for immunohistochemical detection of HER2 protein overexpression in breast cancer tissue routinely processed for histologic evaluation. The HER2 test results are reported in accordance with the ASCO/CAP guideline recommendations for HER2 testing in breast cancer (J Clin Oncol 2007; 25(1):118-145).

4. BREAST, RIGHT, MEDIAL MARGIN; EXCISION:
- BREAST TISSUE WITH LOBULAR CARCINOMA IN SITU (LCIS).
5. BREAST, RIGHT, SUPERIOR MARGIN; EXCISION:
- BREAST TISSUE WITH LOBULAR CARCINOMA IN SITU (LCIS).
6. BREAST, RIGHT, INFERIOR MARGIN; EXCISION:
- BREAST TISSUE WITH LOBULAR CARCINOMA IN SITU (LCIS).
7. BREAST, RIGHT, LATERAL MARGIN; EXCISION:
- BREAST TISSUE WITH LOBULAR CARCINOMA IN SITU (LCIS).
8. BREAST, RIGHT, POSTERIOR MARGIN; EXCISION:
- BENIGN FIBROADIPOSE TISSUE AND SKELETAL MUSCLE.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by . They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

[page 3 of 6]
1) The specimen is received fresh for frozen section consultation labeled "sentinel node #1, level 1, right axilla" and consists of a single lymph node measuring 0.4 cm in greatest dimension. The lymph node is bisected and entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

2) The specimen is received fresh for frozen section consultation labeled "Sentinel node #2, level 1, right axilla" and consists of a single lymph node measuring 1.9 cm in greatest dimension, which is bisected and entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

3) The specimen is received fresh, labeled "Right breast tissue" and consists of an unoriented, 7.2 x 5.5 x 3.3 cm, piece of fibrofatty breast tissue with a needle localization wire. The company specimen radiograph displays the needle localization wire in place and a Bar-clip located at coordinates: F,G-5,6. The specimen is entirely inked black. Serial sectioning reveals the Bar-clip situated within a 2.3 x 2.3 x 2.1 cm, poorly defined, lobular bordered, fatty infiltrating, pink-white mass with fine tan-yellow reticulations, located 0.1 cm from the closest inked resection margin. Partially surrounding the mass is a 4.8 x 4.1 x 3.0 cm area of moderately dense, focally nodular, tan-white fibrous tissue which is separated by scant lobules of yellow-orange adipose. A representative section of the tumor is submitted to TPS. Representative sections are submitted for permanent.

Summary of sections:
MT - tumor and closest tissue edge
FFT -- full face of tumor
T - tumor
RS -- representative sections

4) The specimen is received fresh, labeled "Medial margin, right breast" and consists of a piece of fibrofatty breast tissue measuring 3.8 x 2.1 cm, and 1.0 cm thick. A clip marks the new margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

** Continued on next page **

[page 4 of 6]
----- Page 4 of 6
5) The specimen is received fresh, labeled "Superior margin, right breast" and consists of a piece of fibrofatty breast tissue measuring 3.0 x 2.5 cm, and 1.0 cm thick. A clip marks the new margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

6) The specimen is received fresh, labeled "Inferior margin, right breast" and consists of a piece of fibrofatty breast tissue measuring 2.8 x 1.7 cm, and 0.8 cm thick. A clip marks the new margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

7) The specimen is received fresh, labeled "Lateral margin, right breast" and consists of a piece of fibrofatty breast tissue measuring 5.1 x 2.1 cm, and 1.3 cm thick. A clip marks the new margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

8) The specimen is received fresh, labeled "Posterior margin, right breast" and consists of a piece of fibrofatty breast tissue measuring 2.3 x 1.7 cm, and 0.5 cm thick. A clip marks the new margin of excision, which is inked black. The tissue is serially sectioned and entirely submitted.

Summary of sections:
SS - sequential sections

Summary of Sections:

Part 1: SP: Sentinel node #1 level one right axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Sentinel node #2 level one right axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 3: SP: Right breast tissue

** Continued on next page **

[page 5 of 6]
Block	Sect.	Site	PCs
1		FFT	1
1		MT	1
3		RS	5
4		T	4

Part 4: SP: Medial margin, right breast

Block	Sect.	Site	PCs
5		SS	8

Part 5: SP: Superior margin, right breast

Block	Sect.	Site	PCs
6		SS	8

Part 6: SP: Inferior margin, right breast

Block	Sect.	Site	PCs
3		SS	7

Part 7: SP: Lateral margin, right breast

Block	Sect.	Site	PCs
6		SS	12

Part 8: SP: Posterior margin, right breast

Block	Sect.	Site	PCs
2		SS	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: Sentinel node #1 level one right axilla (fs): Benign
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: SP: Sentinel node #2 level one right axilla (fs): Benign
PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: Sentinel node #1 level one right axilla (fs): Benign
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 6 of 6]
'2)'

FROZEN SECTION DIAGNOSIS: SP: Sentinel node #2 level one right
axilla (fs): Benign

PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file 1583fdc2-c4fe-436e-b037-fee07d2ab3e9 (TCGA-AO-A0J8.03C7A677-C223-47D6-869E-E6C3250B0C08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).